Somatic mutation profile of tumor specimen C3L-01729-01 (aliquot CPT0127610006) from CPTAC case C3L-01729, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.2 years (21,974 days).
Specimen C3L-01729-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d20dd3c-906c-4877-9a6d-3aa240e7de1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01729-72 (Blood Derived Normal), aliquot CPT0127680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c08af51f-03dc-420b-ab4e-393e55be43be

The open-access MAF lists 100 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Frame Shift Del 7, Nonsense Mutation 5, Intron 5, 3'UTR 4, In Frame Del 2, Splice Site 1, Translation Start Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012567148, CM1312460, COSV52431403; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/258 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3R1 | c.1138_1140del p.L380del (on ENST00000521381 / NM_181523.3; = p.L110del on NM_181504.4) | In Frame Del (DEL) | VAF 9/80 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- ALKBH8 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 8/146 reads (5%) | catalogued as COSV52838961; called by muse, mutect2
- ARHGAP44 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 23/392 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs376982735; called by muse, mutect2
- ATXN10 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs202151442; called by muse, mutect2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2
- CLEC1B | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs778816261; called by muse, mutect2
- COL4A2 | c.4275del p.G1426Efs*33 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as COSV100847412, COSV64631360; called by mutect2, pindel, varscan2
- COL9A2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs376234058, COSV65607473; called by muse, mutect2
- DPP8 | c.2615C>T p.S872L (on ENST00000341861 / NM_001320875.2; = p.S756L on NM_017743.6) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1251159108; called by muse, mutect2
- EMSY | c.2470A>G p.I824V | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.102); catalogued as rs777021176; called by muse, mutect2, varscan2
- FASN | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 32/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144193556; called by muse, mutect2
- FIBCD1 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs766248349; called by muse, mutect2
- GABRA3 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64796181, COSV64805725; called by muse, mutect2
- GLI2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs374562179; called by muse, mutect2
- ISY1-RAB43 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1345308257; called by muse, mutect2
- KCNA3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1049290141; called by muse, mutect2, varscan2
- LRRC31 | c.812T>G p.V271G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs1178544096; called by muse, mutect2
- LRRC4B | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV65350561; called by muse, mutect2
- MED12 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1350320350, COSV100380595; called by muse, varscan2
- MMP11 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755891150, COSV53157295; called by muse, mutect2
- NOS2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58224706; called by muse, mutect2
- NUFIP1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752532973, COSV64791247; called by muse, mutect2
- OR14K1 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315027; called by muse, mutect2
- OR5H1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777374780, COSV100641671; called by muse, mutect2
- PLK3 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs1390625254, COSV59499602, COSV59500420; called by muse, mutect2
- PPP5C | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171806958; called by muse, mutect2, varscan2
- PRKDC | c.10534G>A p.V3512I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756722157, COSV100039252; called by muse, mutect2
- PTEN | c.723del p.F241Lfs*15 | Frame Shift Del (DEL) | VAF 33/300 reads (11%) | catalogued as COSV64288616, COSV64291647; called by mutect2, pindel, varscan2
- RO60 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as rs768467310; called by muse, mutect2, varscan2
- SENP3 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV53435689; called by muse, mutect2
- SLITRK1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs759439951, COSV101000066; called by muse, mutect2
- SRP72 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs768536813; called by muse, mutect2
- SYNM | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs972297581, COSV60374730; called by muse, mutect2
- TELO2 | c.1770G>A p.P590= | Splice Region (SNP) | VAF 8/103 reads (8%) | catalogued as rs1215873785, COSV99248089; called by muse, mutect2
- TRRAP | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1249110960; called by muse, mutect2, varscan2
- UGT1A6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 19/207 reads (9%) | catalogued as rs571650145, COSV59382336, COSV59396376; called by muse, mutect2
- ZBED1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1429044374; called by muse, mutect2
- ZGRF1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs535674967, COSV100005690; called by muse, mutect2
- ABCA12 | c.7741G>T p.G2581C (on ENST00000272895 / NM_173076.3; = p.G2263C on NM_015657.3) | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2
- ADGRG4 | c.8385G>T p.L2795F | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGAP2 | c.1285G>A p.G429S (on ENST00000547588 / NM_001122772.2; = p.G93S on NM_014770.4) | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANAPC5 | c.649_652del p.S217Nfs*6 | Frame Shift Del (DEL) | VAF 14/149 reads (9%) | called by mutect2, pindel
- ARMC8 | c.385C>A p.L129M (on ENST00000469044 / NM_001363941.2; = p.L115M on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- BTRC | c.491A>G p.Q164R (on ENST00000370187 / NM_033637.4; = p.Q128R on NM_003939.5) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2
- CD93 | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); called by muse, mutect2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 14/139 reads (10%) | called by mutect2, pindel
- CINP | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- CITED1 | c.547T>A p.F183I | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.5405G>A p.G1802D (on ENST00000297405 / NM_001363185.1; = p.G1698D on NM_052900.3) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC9 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GNS | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2
- HECTD1 | c.250del p.V84Yfs*12 | Frame Shift Del (DEL) | VAF 24/291 reads (8%) | called by mutect2, pindel
- IFT122 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- JPH4 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM4A | c.2943C>A p.H981Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); called by muse, mutect2
- MAP3K21 | c.1634del p.P545Rfs*6 | Frame Shift Del (DEL) | VAF 13/167 reads (8%) | called by mutect2, pindel
- MFGE8 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- MPL | c.408del p.S137Vfs*29 | Frame Shift Del (DEL) | VAF 24/220 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.848A>T p.D283V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PLPPR3 | c.1380_1382del p.D460del (on ENST00000520876 / NM_001270366.2; = p.D488del on NM_024888.2) | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- PRKDC | c.6893+2T>G p.X2298_splice | Splice Site (SNP) | VAF 7/179 reads (4%) | called by muse, mutect2
- SIX3 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TEK | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2
- TSC22D2 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2
- ZBTB16 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ZNF367 | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF433 | c.1375T>G p.F459V | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ZNF443 | c.309T>G p.C103W | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- ABTB2 | c.342C>T p.G114= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- ATP2B3 | c.1011G>A p.A337= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs142541769, COSV54852162; called by muse, mutect2
- AXDND1 | c.186A>G p.E62= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs1203453101; called by muse, mutect2
- C14orf132 | c.159C>T p.N53= (on ENST00000553782 / NM_001289139.2; = p.N22= on NM_001252507.3) | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs761816827; called by muse, mutect2
- CCDC181 | c.1107G>A p.K369= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV63157249; called by muse, mutect2
- CCNI2 | c.192G>A p.A64= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- DENND1C | c.540C>T p.S180= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- EEF2 | c.585C>T p.G195= | Silent (SNP) | VAF 17/210 reads (8%) | catalogued as rs1246304491; called by muse, mutect2
- FAM178B | c.1656C>T p.S552= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- FANCA | c.2022G>A p.S674= | Silent (SNP) | VAF 28/403 reads (7%) | catalogued as rs371997754; called by muse, mutect2
- FNDC1 | c.3078G>A p.R1026= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- HMCN2 | c.1158C>T p.G386= | Silent (SNP) | VAF 8/236 reads (3%) | catalogued as rs547987947; called by muse, mutect2
- KIZ | c.1980C>T p.P660= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as rs1336646328; called by muse, mutect2
- NFRKB | c.1020T>C p.T340= (on ENST00000446488 / NM_001143835.2; = p.T365= on NM_006165.3) | Silent (SNP) | VAF 21/234 reads (9%) | catalogued as rs1013442648; called by muse, mutect2
- NMBR | c.258G>A p.A86= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs757333914, COSV57802675; called by muse, mutect2
- PCDHB13 | c.1797C>T p.N599= | Silent (SNP) | VAF 24/496 reads (5%) | catalogued as rs1312931213; called by muse, mutect2
- PNPLA2 | c.687G>T p.P229= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- RFPL4A | c.102C>T p.C34= | Silent (SNP) | VAF 22/414 reads (5%) | catalogued as rs1031318812; called by muse, mutect2
- RHOXF2B | c.282C>T p.L94= | Silent (SNP) | VAF 36/614 reads (6%) | called by muse, mutect2
- WEE2 | c.198C>T p.L66= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs369284093; called by muse, mutect2
- AL109984.1 | n.186+4925C>T | Intron (SNP) | VAF 26/308 reads (8%) | catalogued as rs775231013, COSV63751185; called by muse, mutect2
- B3GNT4 | c.*943G>A | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- C5orf38 | c.*315G>A | 3'UTR (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- DIP2B | c.-30G>T | 5'UTR (SNP) | VAF 13/322 reads (4%) | called by muse, mutect2
- HSPD1 | c.*40C>T | 3'UTR (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- MMP9 | c.1750+22C>A | Intron (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- MRTFA | c.241+32666G>A | Intron (SNP) | VAF 16/257 reads (6%) | catalogued as rs1384828150; called by muse, mutect2
- SIGMAR1 | c.445+48del | Intron (DEL) | VAF 13/121 reads (11%) | called by mutect2, pindel
- SORBS1 | c.442-826C>T | Intron (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- UQCRB | c.*2165C>T | 3'UTR (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
